National Lung Screening Trial (NLST) participant 106280 — screening results and CT findings
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 66 years; Gender: male; Race: White; Cigarette smoking status at randomisation: current smoker; Enrolled through a Lung Screening Study (LSS) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; this participant has CT screening exam records, so these are low-dose CT screens)
- T0 (day 56): Positive, change unspecified: nodule(s) >= 4 mm or enlarging nodule(s), mass(es), or other non-specific abnormalities suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 100 mA, 58 effective mAs, display field of view 36 cm, reconstruction filter GE, other.
- T1 (day 587): Positive, other. Isolation read, before comparison with prior images: positive (nodule(s) >= 4 mm, mass or other suspicious abnormality). Exam quality: diagnostic CT; technique as recorded on the form: 140 kVp, 75 mA, 43 effective mAs, display field of view 36 cm, reconstruction filter GE Standard / GE Bone.
- T2 (day 867): Positive, other. Isolation read, before comparison with prior images: positive (nodule(s) >= 4 mm, mass or other suspicious abnormality). Exam quality: diagnostic CT; technique as recorded on the form: 140 kVp, 75 mA, 43 effective mAs, display field of view 36 cm, reconstruction filter GE Standard / GE Bone.

Abnormalities recorded by the reading radiologist on the CT screens (18 abnormalities; numbered within each screening year; size, margins, attenuation and location were collected only for non-calcified nodules or masses of at least 4 mm; interval-change items come from the comparison read)
- T0 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left upper lobe; longest diameter 7 mm, longest perpendicular diameter 5 mm; margins poorly defined; predominant attenuation ground glass; greatest diameter on CT slice 15.
- T0 abnormality 2: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left upper lobe; longest diameter 6 mm, longest perpendicular diameter 4 mm; margins poorly defined; predominant attenuation ground glass; greatest diameter on CT slice 39.
- T0 abnormality 3: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left upper lobe; longest diameter 6 mm, longest perpendicular diameter 4 mm; margins poorly defined; predominant attenuation ground glass; greatest diameter on CT slice 41.
- T0 abnormality 4: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right upper lobe; longest diameter 9 mm, longest perpendicular diameter 8 mm; margins poorly defined; predominant attenuation ground glass; greatest diameter on CT slice 42.
- T0 abnormality 5: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left lower lobe; longest diameter 5 mm, longest perpendicular diameter 4 mm; margins poorly defined; predominant attenuation soft tissue; greatest diameter on CT slice 47.
- T0 abnormality 6: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left upper lobe; longest diameter 5 mm, longest perpendicular diameter 4 mm; margins poorly defined; predominant attenuation ground glass; greatest diameter on CT slice 51.
- T1 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right upper lobe; longest diameter 10 mm, longest perpendicular diameter 7 mm; margins could not be determined; predominant attenuation ground glass; greatest diameter on CT slice 65; pre-existing on earlier images (earliest visible day 56); interval growth; no suspicious change in attenuation.
- T1 abnormality 2: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre: other location; longest diameter 8 mm, longest perpendicular diameter 6 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 120; pre-existing on earlier images (earliest visible day 56); no interval growth; no suspicious change in attenuation.
- T1 abnormality 3: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left upper lobe; longest diameter 5 mm, longest perpendicular diameter 5 mm; margins poorly defined; predominant attenuation soft tissue; greatest diameter on CT slice 18; pre-existing on earlier images (earliest visible day 56); no interval growth; no suspicious change in attenuation.
- T1 abnormality 4: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left upper lobe; longest diameter 5 mm, longest perpendicular diameter 5 mm; margins poorly defined; predominant attenuation soft tissue; greatest diameter on CT slice 53; pre-existing on earlier images (earliest visible day 56); no interval growth; no suspicious change in attenuation.
- T1 abnormality 5: Significant cardiovascular abnormality; pre-existing on earlier images (earliest visible day 56); interval change does not warrant further investigation.
- T1 abnormality 6: Other minor abnormality noted.
- T2 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left upper lobe; longest diameter 8 mm, longest perpendicular diameter 5 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 44; pre-existing on earlier images (earliest visible day 56); no interval growth; no suspicious change in attenuation.
- T2 abnormality 2: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left upper lobe; longest diameter 7 mm, longest perpendicular diameter 4 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 49; pre-existing on earlier images (earliest visible day 56); no interval growth; no suspicious change in attenuation.
- T2 abnormality 3: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left upper lobe; longest diameter 10 mm, longest perpendicular diameter 9 mm; margins smooth; predominant attenuation ground glass; greatest diameter on CT slice 33; pre-existing on earlier images (earliest visible day 56); no interval growth; no suspicious change in attenuation.
- T2 abnormality 4: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left upper lobe; longest diameter 5 mm, longest perpendicular diameter 5 mm; margins smooth; predominant attenuation ground glass; greatest diameter on CT slice 45; pre-existing on earlier images (earliest visible day 56); interval growth; no suspicious change in attenuation.
- T2 abnormality 5: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left lower lobe; longest diameter 7 mm, longest perpendicular diameter 6 mm; margins smooth; predominant attenuation ground glass; greatest diameter on CT slice 118; pre-existing on earlier images (earliest visible day 56); no interval growth; no suspicious change in attenuation.
- T2 abnormality 6: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right upper lobe; longest diameter 4 mm, longest perpendicular diameter 4 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 43; pre-existing on earlier images (earliest visible day 56); interval growth; no suspicious change in attenuation.

Follow-up
No confirmed lung cancer during the trial; Last known free of lung cancer: day 1,913.
